Somatic mutation profile of tumor specimen TCGA-13-0884-01B (aliquot TCGA-13-0884-01B-01W-0492-08) from TCGA case TCGA-13-0884, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 39.8 years (14,538 days).
Specimen TCGA-13-0884-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90c4287a-4b3d-40db-8d35-c88155b5767b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0884-10A (Blood Derived Normal), aliquot TCGA-13-0884-10A-01W-0494-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f8a0857-bab4-4f5e-b648-f2e792ad22f9

The open-access MAF lists 121 somatic variants for this specimen: 96 protein-altering or splice-affecting, 22 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 22, Frame Shift Del 8, Nonsense Mutation 7, Splice Region 2, Splice Site 2, In Frame Del 2, Frame Shift Ins 1, 3'Flank 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNTNAP1 | c.1869G>A p.W623* | Nonsense Mutation (SNP) | VAF 44/149 reads (30%) | catalogued as rs878853221, COSV52851069; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.4168dup p.A1390Gfs*42 | Frame Shift Ins (INS) | VAF 10/93 reads (11%) | catalogued as rs756471180; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 42/84 reads (50%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACP2 | c.610T>C p.W204R | Missense Mutation (SNP) | VAF 70/542 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as COSV57042774; called by muse, mutect2, varscan2
- ACVR1 | c.1485G>C p.L495F | Missense Mutation (SNP) | VAF 99/361 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55119435; called by muse, mutect2, varscan2
- ADAMTS16 | c.764-2A>G p.X255_splice | Splice Site (SNP) | VAF 60/746 reads (8%) | catalogued as COSV56992275; called by muse, mutect2
- AGFG1 | c.1568A>G p.K523R | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.874); catalogued as COSV59512349; called by muse, mutect2, varscan2
- ANTXR2 | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55018840; called by muse, mutect2
- ATL2 | c.311G>C p.R104P | Missense Mutation (SNP) | VAF 76/487 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60052406, COSV60053137; called by muse, mutect2, varscan2
- ATRX | c.7205T>G p.I2402S | Missense Mutation (SNP) | VAF 51/529 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV100970044; called by muse, mutect2
- BANK1 | c.281C>T p.T94I | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV59843725; called by muse, mutect2, varscan2
- BIRC3 | c.743C>G p.S248C | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as rs373514370; called by muse, mutect2, varscan2
- BMPR2 | c.2921G>C p.R974P | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65809966; called by muse, mutect2, varscan2
- BPIFB6 | c.303-2A>G p.X101_splice | Splice Site (SNP) | VAF 74/554 reads (13%) | catalogued as COSV62755404; called by muse, mutect2, varscan2
- C1orf127 | c.686G>C p.R229T | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.382); catalogued as COSV65437524; called by muse, mutect2, varscan2
- CA5B | c.10A>G p.M4V | Missense Mutation (SNP) | VAF 20/447 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1455096191, COSV100590682; called by muse, mutect2
- CCDC33 | c.535A>T p.M179L | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV58352717; called by muse, mutect2, varscan2
- CDC25B | c.1196C>G p.A399G (on ENST00000245960 / NM_021873.3; = p.A385G on NM_004358.4) | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.083); catalogued as COSV55657143; called by muse, mutect2, varscan2
- CDSN | c.1572G>C p.E524D | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); catalogued as COSV52538442; called by muse, mutect2, varscan2
- CLVS1 | c.163C>G p.Q55E | Missense Mutation (SNP) | VAF 45/578 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57975873; called by muse, mutect2
- CNBD2 | c.304G>T p.D102Y | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV62587099; called by muse, mutect2, varscan2
- COL4A1 | c.4099C>T p.P1367S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as COSV65426889; called by muse, mutect2, varscan2
- COL4A4 | c.3219C>G p.N1073K | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV100306209; called by muse, mutect2
- COL6A3 | c.9228A>C p.T3076= | Splice Region (SNP) | VAF 20/66 reads (30%) | catalogued as COSV55092368; called by muse, mutect2, varscan2
- CSMD3 | c.2588G>A p.G863E (on ENST00000297405 / NM_001363185.1; = p.G759E on NM_052900.3) | Missense Mutation (SNP) | VAF 189/498 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52198978; called by muse, mutect2, varscan2
- CTTNBP2 | c.4850G>C p.R1617T | Missense Mutation (SNP) | VAF 124/459 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as COSV50407162; called by muse, mutect2, varscan2
- DDX42 | c.2572C>T p.R858W | Missense Mutation (SNP) | VAF 120/349 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.336); catalogued as rs533590615, COSV63790301; called by muse, mutect2, varscan2
- DNAH3 | c.10434T>G p.C3478W | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54526033; called by muse, mutect2, varscan2
- DNAH7 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 33/268 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100413823; called by muse, mutect2, varscan2
- DSCAM | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.992); catalogued as COSV68028085; called by muse, mutect2, varscan2
- EFR3A | c.133G>C p.V45L | Missense Mutation (SNP) | VAF 119/256 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54458139; called by muse, mutect2, varscan2
- ERC1 | c.2479C>T p.Q827* (on ENST00000360905 / NM_178040.4; = p.Q799* on NM_178039.4) | Nonsense Mutation (SNP) | VAF 22/109 reads (20%) | catalogued as rs753152606, COSV61695669; called by muse, mutect2, varscan2
- FAM24A | c.244T>C p.C82R | Missense Mutation (SNP) | VAF 49/349 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as COSV64405966; called by muse, mutect2, varscan2
- FAM98B | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as COSV59842989; called by muse, mutect2, varscan2
- FLT1 | c.636T>A p.N212K | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.627); catalogued as COSV56729639; called by muse, mutect2, varscan2
- GPX6 | c.313G>T p.G105* | Nonsense Mutation (SNP) | VAF 19/79 reads (24%) | catalogued as COSV62657724; called by muse, mutect2, varscan2
- HOXD10 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.196); catalogued as rs1162064144, COSV50892093, COSV50893287; called by muse, mutect2, varscan2
- HSPG2 | c.3184C>A p.Q1062K | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV65972374, COSV65974140; called by muse, mutect2, varscan2
- INTS13 | c.106A>G p.N36D | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.257); catalogued as COSV53902990; called by muse, mutect2, varscan2
- LAMC2 | c.3544C>G p.P1182A | Missense Mutation (SNP) | VAF 57/376 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV51456225; called by muse, mutect2, varscan2
- LASP1 | c.596C>A p.A199D | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.055); catalogued as COSV100530297; called by muse, mutect2, varscan2
- LMBRD1 | c.1448C>T p.S483F (on ENST00000649011; = p.S461F on NM_018368.4) | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV100992537, COSV65296787; called by muse, mutect2, varscan2
- LNX2 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 35/212 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV60336069; called by muse, mutect2, varscan2
- MADD | c.4262C>T p.A1421V | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs146118440; called by muse, mutect2, varscan2
- MEIS2 | c.232G>A p.D78N (on ENST00000561208 / NM_170675.5; = p.D65N on NM_002399.3) | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV54937074; called by muse, mutect2, varscan2
- MTHFD1 | c.626G>C p.G209A | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53700939; called by muse, mutect2, varscan2
- MXRA5 | c.260A>C p.H87P | Missense Mutation (SNP) | VAF 51/180 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54237698; called by muse, mutect2, varscan2
- MYH7B | c.1642G>C p.E548Q | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99482274; called by muse, mutect2
- NRP1 | c.1268G>C p.G423A | Missense Mutation (SNP) | VAF 47/788 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV55168492, COSV55170705; called by muse, mutect2
- OR4N5 | c.851C>A p.P284H | Missense Mutation (SNP) | VAF 119/547 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100374201, COSV61320719; called by muse, mutect2, varscan2
- OR9Q2 | c.314C>A p.T105N | Missense Mutation (SNP) | VAF 69/464 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV61112058; called by muse, mutect2, varscan2
- PKD2L1 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 23/213 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs193920845, COSV58399502; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLAG1 | c.512C>G p.S171C | Missense Mutation (SNP) | VAF 19/337 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV100387706; called by muse, mutect2
- PLAGL2 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV55788531; called by muse, mutect2, varscan2
- PLEKHG7 | c.1711A>C p.K571Q | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as COSV100760034; called by muse, mutect2
- PRDM9 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 14/90 reads (16%) | catalogued as COSV57003733, COSV57008674; called by muse, mutect2, varscan2
- PTCHD1 | c.1735A>G p.T579A | Missense Mutation (SNP) | VAF 116/691 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV65060448; called by muse, mutect2, varscan2
- PTPRN2 | c.1500A>T p.Q500H | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as COSV101233638; called by muse, mutect2, varscan2
- ROR2 | c.1547C>T p.P516L | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.192); catalogued as rs775860567, COSV65219730; called by muse, mutect2, varscan2
- RPH3A | c.1355G>A p.R452Q (on ENST00000389385 / NM_001143854.2; = p.R448Q on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs767497432, COSV66991337, COSV66991418; called by muse, mutect2, varscan2
- RRP12 | c.1307C>T p.T436M | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV59668175; called by muse, mutect2
- RTL5 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as rs1253620985, COSV65452956; called by muse, mutect2, varscan2
- SENP8 | c.525T>A p.C175* | Nonsense Mutation (SNP) | VAF 56/245 reads (23%) | catalogued as COSV61768032, COSV61768324; called by muse, mutect2, varscan2
- SHROOM3 | c.1917G>A p.W639* | Nonsense Mutation (SNP) | VAF 20/115 reads (17%) | catalogued as COSV99933523; called by muse, mutect2, varscan2
- SLC34A2 | c.770G>C p.G257A | Missense Mutation (SNP) | VAF 90/338 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV101158270, COSV65941784; called by muse, mutect2, varscan2
- SLC39A11 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 67/131 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs202154945, COSV55290302; called by muse, mutect2, varscan2
- SLC4A7 | c.2188C>G p.L730V | Missense Mutation (SNP) | VAF 50/483 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99839194; called by muse, mutect2, varscan2
- SOX5 | c.641A>T p.E214V | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58632044; called by muse, mutect2, varscan2
- SRRM4 | c.1511T>G p.L504R | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV57417872, COSV99938900; called by muse, mutect2, varscan2
- STAT1 | c.2200G>C p.V734L | Missense Mutation (SNP) | VAF 51/254 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63116415; called by muse, mutect2, varscan2
- STK26 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 53/195 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as rs1469596591, COSV53746588; called by muse, mutect2, varscan2
- SVEP1 | c.10037G>A p.S3346N | Missense Mutation (SNP) | VAF 83/378 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV52839976; called by muse, mutect2, varscan2
- TAF1L | c.41C>A p.T14N | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.003); catalogued as COSV99644103; called by muse, varscan2
- TCF20 | c.5492C>G p.T1831S | Missense Mutation (SNP) | VAF 84/352 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV59491975; called by muse, mutect2, varscan2
- TDRD6 | c.2926T>C p.F976L | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV60176228; called by muse, mutect2, varscan2
- TENM1 | c.6870G>T p.E2290D | Missense Mutation (SNP) | VAF 100/435 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.503); catalogued as COSV64433545; called by muse, mutect2, varscan2
- TRIM21 | c.1309G>A p.A437T | Missense Mutation (SNP) | VAF 79/216 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.017); catalogued as COSV54344522; called by muse, mutect2, varscan2
- UBXN7 | c.736G>T p.D246Y | Missense Mutation (SNP) | VAF 82/316 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV56355862; called by muse, mutect2, varscan2
- XIRP1 | c.1634G>C p.G545A | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61138855; called by muse, mutect2, varscan2
- ZFHX4 | c.7885A>C p.N2629H | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV50922859; called by muse, mutect2, varscan2
- ZFPM2 | c.982T>C p.F328L | Missense Mutation (SNP) | VAF 109/712 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV101022979; called by muse, mutect2, varscan2
- ZNF160 | c.445A>C p.T149P | Missense Mutation (SNP) | VAF 18/396 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100762225; called by muse, mutect2
- ZNF214 | c.1621C>T p.L541F | Missense Mutation (SNP) | VAF 23/320 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99547186; called by muse, mutect2
- ZNF329 | c.617C>T p.T206I | Missense Mutation (SNP) | VAF 59/216 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs45577535, COSV100798667; called by muse, mutect2, varscan2
- ZNF608 | c.1769A>T p.D590V | Missense Mutation (SNP) | VAF 58/249 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV60438343; called by muse, mutect2, varscan2
- ADGRE4P | n.208C>T | Splice Region (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2
- C8orf76 | c.777_787del p.T260Sfs*35 | Frame Shift Del (DEL) | VAF 51/238 reads (21%) | called by mutect2, pindel, varscan2
- GABRA2 | c.589_590del p.I197Lfs*7 | Frame Shift Del (DEL) | VAF 9/76 reads (12%) | called by pindel, varscan2
- KDM6A | c.3157_3174del p.K1053_K1058del | In Frame Del (DEL) | VAF 22/126 reads (17%) | called by mutect2, pindel, varscan2
- OSBPL9 | c.348_360del p.Q117Rfs*13 | Frame Shift Del (DEL) | VAF 8/74 reads (11%) | called by mutect2, pindel, varscan2
- PDE6C | c.1208del p.A403Vfs*32 | Frame Shift Del (DEL) | VAF 84/567 reads (15%) | called by mutect2, pindel, varscan2
- SNX2 | c.1314_1351del p.N438Kfs*15 | Frame Shift Del (DEL) | VAF 13/58 reads (22%) | called by mutect2, pindel
- SYN3 | c.462_464del p.S154del | In Frame Del (DEL) | VAF 30/214 reads (14%) | called by pindel, varscan2
- TACC2 | c.6712del p.T2238Rfs*8 (on ENST00000334433; = p.T316Rfs*8 on NM_006997.4) | Frame Shift Del (DEL) | VAF 10/53 reads (19%) | called by pindel, varscan2
- USP22 | c.613del p.L205Cfs*51 | Frame Shift Del (DEL) | VAF 43/112 reads (38%) | called by mutect2, pindel, varscan2
- XKR9 | c.336del p.F113Sfs*13 | Frame Shift Del (DEL) | VAF 36/345 reads (10%) | called by mutect2, varscan2
- AC008397.2 | c.1449G>A p.K483= | Silent (SNP) | VAF 23/109 reads (21%) | called by muse, mutect2, varscan2
- ADAM32 | c.1170G>A p.P390= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs201298341, COSV65949958; called by muse, varscan2
- ALMS1 | c.7872C>A p.A2624= | Silent (SNP) | VAF 45/256 reads (18%) | catalogued as COSV52511480; called by muse, mutect2, varscan2
- ANXA6 | c.189G>A p.K63= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as rs369346632, COSV100636773; called by muse, mutect2, varscan2
- ASMTL | c.1491A>G p.G497= | Silent (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2
- CCDC171 | c.3163C>T p.L1055= | Silent (SNP) | VAF 47/497 reads (9%) | catalogued as rs1391854322, COSV99899876; called by muse, mutect2, varscan2
- CCDC8 | c.699C>T p.S233= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs769220827, COSV56773635; called by muse, mutect2, varscan2
- EPRS1 | c.2595A>G p.K865= | Silent (SNP) | VAF 94/438 reads (21%) | catalogued as COSV65099358; called by muse, mutect2, varscan2
- FRMPD1 | c.2745C>T p.N915= | Silent (SNP) | VAF 20/117 reads (17%) | catalogued as rs1488612513, COSV66700615; called by muse, mutect2, varscan2
- GRID1 | c.1437C>T p.G479= | Silent (SNP) | VAF 125/739 reads (17%) | catalogued as COSV60032074; called by muse, mutect2, varscan2
- GSPT1 | c.198G>T p.P66= (on ENST00000420576 / NM_001130007.2; = p.P204= on NM_002094.4) | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV70452705; called by muse, mutect2, varscan2
- HIPK2 | c.1812C>G p.S604= | Silent (SNP) | VAF 38/209 reads (18%) | catalogued as COSV61228213; called by muse, mutect2, varscan2
- HTT | c.1668G>A p.S556= | Silent (SNP) | VAF 42/206 reads (20%) | catalogued as COSV61863165; called by muse, mutect2, varscan2
- IP6K1 | c.450G>A p.K150= | Silent (SNP) | VAF 13/138 reads (9%) | catalogued as COSV100391223, COSV58662764; called by muse, mutect2
- KIF2C | c.1119C>A p.I373= | Silent (SNP) | VAF 10/292 reads (3%) | called by muse, mutect2
- MAGEA10 | c.555G>T p.L185= | Silent (SNP) | VAF 20/105 reads (19%) | catalogued as COSV99726569; called by muse, mutect2, varscan2
- NLRP9 | c.1971T>A p.P657= | Silent (SNP) | VAF 21/258 reads (8%) | catalogued as COSV60463925; called by muse, mutect2
- PCDHB16 | c.507C>T p.N169= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV53363357; called by muse, mutect2, varscan2
- SULT6B1 | c.906G>A p.Q302= (on ENST00000535679 / NM_001367551.1; = p.Q264= on NM_001032377.2) | Silent (SNP) | VAF 9/142 reads (6%) | catalogued as COSV99572981; called by muse, mutect2
- TET1 | c.3621T>G p.P1207= | Silent (SNP) | VAF 19/156 reads (12%) | catalogued as COSV65385289; called by muse, mutect2, varscan2
- TNPO3 | c.478C>A p.R160= | Silent (SNP) | VAF 44/235 reads (19%) | catalogued as rs752037576, COSV55282377; called by muse, mutect2, varscan2
- VDR | c.1104C>A p.R368= | Silent (SNP) | VAF 16/103 reads (16%) | catalogued as rs35435255, COSV99968542; called by muse, mutect2, varscan2
- EPSTI1 | chr13:42888486 A>G | 3'Flank (SNP) | VAF 73/292 reads (25%) | catalogued as rs1350249824, COSV58045831; called by muse, mutect2, varscan2
- SNORD113-5 | n.8A>G | RNA (SNP) | VAF 68/252 reads (27%) | catalogued as rs565969072; called by muse, mutect2, varscan2
- ZFHX3 | c.-533+30A>G | Intron (SNP) | VAF 7/21 reads (33%) | catalogued as COSV73947911; called by muse, mutect2, varscan2
